Somatic mutation profile of tumor specimen 0DA6R1 from CCDI case PBBIRB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,783 days).
Specimen 0DA6R1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2d3f2d5-41b0-4603-b4dc-0207fa0d86ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA6QI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9bb8c69-768c-4783-965d-4275cb05d466

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 227/454 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC183 | c.1600_1602del p.K534del | In Frame Del (DEL) | VAF 77/382 reads (20%) | catalogued as rs759937715; called by pindel, varscan2
- CD5L | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 88/776 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199701364; called by muse, mutect2, varscan2
- DHX8 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52251292; called by muse, mutect2, varscan2
- MTNR1B | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV99924951; called by muse, mutect2, varscan2
- MYO3A | c.4546-2A>G p.X1516_splice | Splice Site (SNP) | VAF 81/212 reads (38%) | catalogued as rs765721461; called by muse, mutect2, varscan2
- NOP16 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 275/510 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs776742412; called by muse, mutect2, varscan2
- AFDN | c.2786T>C p.L929P | Missense Mutation (SNP) | VAF 80/597 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- AOX1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 238/833 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRRC75A | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 108/805 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZFHX3 | c.4873C>G p.R1625G | Missense Mutation (SNP) | VAF 122/511 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK2 | c.8841C>T p.D2947= | Silent (SNP) | VAF 169/366 reads (46%) | catalogued as rs751707241; called by muse, mutect2, varscan2
- RYR1 | c.2544C>T p.T848= | Silent (SNP) | VAF 63/714 reads (9%) | catalogued as rs140374285; ClinVar: likely benign; called by muse, mutect2
- UXS1 | c.277-16C>T | Intron (SNP) | VAF 28/561 reads (5%) | catalogued as rs760086885; called by muse, mutect2
